Somatic mutation profile of tumor specimen TCGA-WB-A81F-01A (aliquot TCGA-WB-A81F-01A-11D-A35I-08) from TCGA case TCGA-WB-A81F, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 40.9 years (14,933 days).
Specimen TCGA-WB-A81F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4beff749-cd78-4fde-bef3-08a2b7c6eb2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81F-10A (Blood Derived Normal), aliquot TCGA-WB-A81F-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94262d7d-037d-466a-bd04-dc7f9c958d1d

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF13B | c.2539A>G p.R847G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1399905993; called by muse, mutect2, varscan2
- CEP164 | c.3970T>G p.L1324V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GBP1 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EBF3 | c.1473T>C p.N491= (on ENST00000355311 / NM_001375392.1; = p.N482= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
